Somatic mutation profile of tumor specimen TCGA-2X-A9D6-01A (aliquot TCGA-2X-A9D6-01A-11D-A435-10) from TCGA case TCGA-2X-A9D6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 42.1 years (15,371 days).
Specimen TCGA-2X-A9D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a65c590-a928-4ea0-a099-6d5aa71ef00a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2X-A9D6-10A (Blood Derived Normal), aliquot TCGA-2X-A9D6-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffaf9e68-5438-494f-b311-2ac40a21bddd

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, In Frame Ins 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM83G | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755655474; called by muse, mutect2, varscan2
- KNTC1 | c.6399C>G p.I2133M | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV61078996; called by muse, mutect2
- SYNE1 | c.8974G>A p.D2992N (on ENST00000367255 / NM_182961.4; = p.D2999N on NM_033071.3) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV55021700; called by muse, mutect2, varscan2
- MRPL40 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MTA2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NF1 | c.232_233del p.N78Ffs*28 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- OR52D1 | c.222_224dup p.A75dup | In Frame Ins (INS) | VAF 14/149 reads (9%) | called by mutect2, pindel
- PPP1R3A | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2
- SLC2A1 | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRIM28 | c.1523T>A p.V508D | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBD | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP2C2 | c.630G>A p.T210= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs200504983; called by muse, mutect2, varscan2
